Somatic mutation profile of tumor specimen TCGA-66-2781-01A (aliquot TCGA-66-2781-01A-01D-1522-08) from TCGA case TCGA-66-2781, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.0 years (24,471 days).
Specimen TCGA-66-2781-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 706658b6-b604-4156-a5ba-c9aaa1322e30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2781-11A (Solid Tissue Normal), aliquot TCGA-66-2781-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73c2afdc-d3d7-4f83-82ec-d031a1fca527

The open-access MAF lists 131 somatic variants for this specimen: 104 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 92, Silent 27, Frame Shift Del 5, Nonsense Mutation 4, Splice Site 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF2 | c.1451G>T p.R484L (on ENST00000296862 / NM_001368115.2; = p.R416L on NM_153839.7) | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370408589, COSV57291596; called by muse, varscan2
- ADORA2A | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.127); catalogued as rs767602595, COSV58379706, COSV58380380; called by muse, mutect2, varscan2
- AK9 | c.2911G>A p.E971K | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV58137635, COSV58149603; called by muse, mutect2, varscan2
- AOAH | c.1702G>T p.V568L | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.219); catalogued as COSV51749756; called by muse, varscan2
- ASB7 | c.904C>G p.P302A | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV60419100; called by muse, mutect2, varscan2
- ATP8B3 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as rs935509808, COSV59547863; called by muse, mutect2, varscan2
- ATRX | c.5807A>C p.K1936T | Missense Mutation (SNP) | VAF 87/438 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV64873056, COSV64882465; called by muse, mutect2, varscan2
- CA3 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557237110, COSV53409536, COSV53411192; called by muse, mutect2, varscan2
- CDC42EP4 | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1303517779, COSV59964015; called by muse, mutect2, varscan2
- CDH15 | c.2280C>G p.D760E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); catalogued as COSV57026976; called by muse, mutect2, varscan2
- CEP290 | c.1622A>T p.E541V | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58355332; called by muse, mutect2
- CLCN7 | c.933C>G p.S311R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51973407; called by muse, mutect2, varscan2
- CLEC4F | c.813C>A p.N271K | Missense Mutation (SNP) | VAF 81/321 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV55481375; called by muse, mutect2, varscan2
- CNR1 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62990894; called by muse, mutect2
- CNTNAP1 | c.439C>A p.R147S | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52853172, COSV52853898; called by muse, mutect2, varscan2
- COL1A2 | c.3846G>T p.E1282D | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.682); catalogued as COSV51964969; called by muse, mutect2, varscan2
- COX4I2 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 61/222 reads (27%) | catalogued as COSV65782029; called by muse, mutect2, varscan2
- CPT1B | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV56418701; called by muse, mutect2, varscan2
- CUX1 | c.3271G>C p.E1091Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV52913102; called by mutect2, varscan2
- DISP1 | c.2270C>G p.S757W | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52664251, COSV99450250, COSV99451560; called by muse, mutect2, varscan2
- DNAH1 | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV70235216; called by muse, mutect2, varscan2
- DNAH8 | c.12380G>A p.R4127H | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs771763512, COSV59476004; called by muse, mutect2, varscan2
- DOCK2 | c.3370G>T p.D1124Y | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV56983897, COSV56994056; called by muse, mutect2, varscan2
- ECEL1 | c.2326T>C p.*776Rext*78 | Nonstop Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV58814091; called by muse, mutect2, varscan2
- ELOA2 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV55307469; called by muse, mutect2, varscan2
- EPHB6 | c.470C>A p.T157K | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67420588; called by muse, mutect2, varscan2
- ESRRG | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV63178277; called by muse, mutect2, varscan2
- FCN1 | c.56T>C p.F19S | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV65662825; called by muse, mutect2, varscan2
- FLG2 | c.5119C>A p.H1707N | Missense Mutation (SNP) | VAF 116/672 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.084); catalogued as COSV66172384; called by muse, mutect2, varscan2
- GABRB2 | c.493A>T p.R165W | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50938748; called by muse, mutect2, varscan2
- GCN1 | c.1520-1G>C p.X507_splice | Splice Site (SNP) | VAF 51/130 reads (39%) | catalogued as COSV56114027; called by muse, mutect2, varscan2
- GRIA1 | c.993G>C p.W331C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53621482; called by muse, mutect2, varscan2
- GUCY1A1 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV56655789; called by muse, mutect2, varscan2
- HCN1 | c.2496G>C p.R832S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV57500191, COSV57534251; called by muse, mutect2, varscan2
- HCN1 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 20/188 reads (11%) | catalogued as COSV100299615, COSV57512773, COSV57534258; called by muse, mutect2, varscan2
- HELZ | c.4378G>A p.E1460K | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs1345990820, COSV62380603; called by muse, mutect2, varscan2
- HIVEP1 | c.6586G>T p.D2196Y | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65104581; called by muse, mutect2, varscan2
- ITLN1 | c.582T>A p.Y194* | Nonsense Mutation (SNP) | VAF 105/347 reads (30%) | catalogued as COSV58276627; called by muse, mutect2, varscan2
- KDM7A | c.2647G>A p.G883S | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.877); catalogued as COSV50095368; called by muse, mutect2, varscan2
- KEL | c.1767G>T p.Q589H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as rs138511569; called by muse, mutect2, varscan2
- LCT | c.3563G>T p.S1188I | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); catalogued as COSV51556523; called by muse, mutect2, varscan2
- LONRF3 | c.1915C>T p.H639Y (on ENST00000371628 / NM_001031855.3; = p.H598Y on NM_024778.5) | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as COSV59156193; called by muse, mutect2, varscan2
- LPAR3 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV65454895; called by muse, mutect2, varscan2
- LRP2 | c.11019C>A p.S3673R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV55570975; called by muse, mutect2
- LRP2 | c.9575G>A p.R3192Q | Missense Mutation (SNP) | VAF 108/400 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs753667280, COSV55539839, COSV55546510; called by muse, varscan2
- MAGEB2 | c.398C>A p.T133K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as rs920443442, COSV66781603; called by muse, mutect2, varscan2
- MAK | c.1780G>C p.A594P | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV57567412; called by muse, mutect2, varscan2
- MAP3K19 | c.2017C>T p.H673Y | Missense Mutation (SNP) | VAF 53/410 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as COSV59641755; called by muse, mutect2, varscan2
- MDGA2 | c.2866C>A p.P956T (on ENST00000399232 / NM_001113498.2; = p.P658T on NM_182830.4) | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62112904; called by muse, mutect2
- MTHFD1 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53703295; called by muse, mutect2, varscan2
- MUC16 | c.32452C>T p.P10818S | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.042); catalogued as rs1336463573, COSV67489335; called by muse, mutect2, varscan2
- MYCBP2 | c.4314A>T p.E1438D (on ENST00000357337; = p.E1476D on NM_015057.5) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV62036701; called by muse, mutect2, varscan2
- MYH13 | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV52826321; called by muse, mutect2, varscan2
- MYPN | c.2575G>A p.G859R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs747848627, COSV62734277; called by muse, mutect2, varscan2
- NAALAD2 | c.1619C>A p.P540Q | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58965446; called by muse, mutect2, varscan2
- NARF | c.39G>T p.K13N | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV59113452; called by muse, mutect2, varscan2
- NDUFA10 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV53155327, COSV53156354; called by muse, mutect2, varscan2
- NEDD9 | c.1733A>T p.E578V | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as COSV65223113; called by muse, mutect2, varscan2
- NIF3L1 | c.638G>A p.C213Y (on ENST00000409020 / NM_001369444.1; = p.C186Y on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1456427564, COSV62900862; called by muse, mutect2, varscan2
- NLRP14 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV55071485; called by muse, mutect2, varscan2
- NPSR1 | c.139T>C p.S47P | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs1260501119, COSV62206794; called by muse, mutect2, varscan2
- OBSCN | c.15214G>A p.V5072I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV52818665; called by muse, mutect2, varscan2
- OPRM1 | c.1111A>C p.N371H | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.593); catalogued as COSV57684457; called by muse, mutect2, varscan2
- OR10AD1 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV59613013; called by muse, mutect2, varscan2
- OR2T1 | c.761C>A p.A254D | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63542767; called by muse, mutect2, varscan2
- OR4K13 | c.787A>T p.S263C | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV59860663; called by muse, mutect2
- OR6S1 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as COSV57839108; called by muse, mutect2, varscan2
- PADI1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1251581287, COSV64939195; called by muse, mutect2, varscan2
- PARPBP | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.346); catalogued as COSV59676224; called by muse, mutect2, varscan2
- PCDH11X | c.3497C>T p.A1166V | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV53444640, COSV53499264; called by muse, mutect2, varscan2
- PCDH11X | c.3817C>A p.Q1273K | Missense Mutation (SNP) | VAF 115/235 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53499277; called by muse, mutect2, varscan2
- PCOLCE2 | c.439A>C p.N147H | Missense Mutation (SNP) | VAF 116/185 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56001718; called by muse, mutect2, varscan2
- PDE2A | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as rs1489634006, COSV57812811; called by muse, mutect2
- PGK2 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs775953760, COSV59165402; called by muse, mutect2, varscan2
- PLEKHH1 | c.3791T>C p.V1264A | Missense Mutation (SNP) | VAF 53/396 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV53615162; called by muse, mutect2, varscan2
- PLGRKT | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56352277; called by muse, mutect2, varscan2
- PPIP5K2 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs782341831, COSV58609109; called by muse, mutect2, varscan2
- RANBP2 | c.3814G>A p.A1272T | Missense Mutation (SNP) | VAF 66/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51707645; called by muse, mutect2, varscan2
- RAP1GAP | c.1064T>C p.F355S | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51577382; called by muse, mutect2, varscan2
- RC3H1 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV51214153; called by muse, mutect2, varscan2
- REG1B | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59305802, COSV59307627; called by muse, mutect2, varscan2
- SACS | c.2961G>C p.K987N | Missense Mutation (SNP) | VAF 72/291 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as COSV66546104; called by muse, mutect2, varscan2
- SALL3 | c.3146C>A p.T1049N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV73306482; called by muse, mutect2, varscan2
- SHCBP1 | c.44C>G p.A15G | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV57650036; called by muse, mutect2, varscan2
- SI | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as rs1247427505, COSV52285353, COSV52298193; called by muse, mutect2, varscan2
- SLC34A3 | c.1558C>A p.P520T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs1174954373, COSV63187965; called by muse, mutect2, varscan2
- SPNS1 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 56/174 reads (32%) | catalogued as COSV57956328, COSV57956546; called by muse, mutect2, varscan2
- SRSF11 | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.225); catalogued as COSV63937033; called by muse, mutect2, varscan2
- TG | c.6758G>T p.G2253V | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55091965; called by muse, mutect2, varscan2
- TP53 | c.687_688del p.T230Hfs*9 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as COSV52738764; called by mutect2, pindel, varscan2
- TRIM56 | c.2233A>G p.I745V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.785); catalogued as COSV60161131; called by muse, mutect2, varscan2
- TRPS1 | c.52G>T p.G18C (on ENST00000220888 / NM_001330599.2; = p.G31C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/141 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); catalogued as COSV55259068, COSV99629266; called by muse, mutect2, varscan2
- TYW1 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as COSV62755749, COSV62756396; called by muse, mutect2, varscan2
- USH2A | c.12916C>A p.L4306I | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.265); catalogued as COSV100237394, COSV56425339; called by muse, mutect2, varscan2
- ZFP82 | c.672A>T p.K224N | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67566589; called by muse, mutect2
- ZFYVE1 | c.646T>C p.S216P | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59612857; called by muse, mutect2, varscan2
- ZNF169 | c.720del p.R241Efs*91 | Frame Shift Del (DEL) | VAF 30/89 reads (34%) | catalogued as COSV100566315, COSV61763016; called by mutect2, pindel, varscan2
- ZNF197 | c.2723G>A p.G908E | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV56077372; called by muse, mutect2, varscan2
- ZNF430 | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV55112327; called by muse, mutect2, varscan2
- ZNF689 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1012521679, COSV54909996; called by muse, mutect2, varscan2
- ADGRL3 | c.567del p.Y189* (on ENST00000506720 / NM_001322402.2; = p.Y121* on NM_015236.6) | Frame Shift Del (DEL) | VAF 104/426 reads (24%) | called by mutect2, pindel, varscan2
- CHD3 | c.4359-3_4398del p.X1453_splice | Splice Site (DEL) | VAF 20/162 reads (12%) | called by mutect2, pindel
- PLCL1 | c.3031del p.A1011Qfs*5 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- ZNF791 | c.435del p.K145Nfs*116 | Frame Shift Del (DEL) | VAF 44/171 reads (26%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.522C>T p.P174= | Silent (SNP) | VAF 36/197 reads (18%) | catalogued as rs751460021, COSV54685854; called by muse, mutect2, varscan2
- C1orf87 | c.1185G>A p.L395= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as rs765248043, COSV64597613; called by muse, mutect2, varscan2
- CA10 | c.477C>A p.I159= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV53369023; called by muse, mutect2, varscan2
- CDC42EP4 | c.228C>G p.R76= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV59963282, COSV59964025; called by muse, mutect2, varscan2
- FAT3 | c.13428G>T p.P4476= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs376130419, COSV53165409; called by muse, mutect2, varscan2
- FLG | c.9498T>C p.R3166= | Silent (SNP) | VAF 231/788 reads (29%) | catalogued as COSV64247745; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.402C>T p.V134= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV58564553; called by muse, mutect2
- HKDC1 | c.900G>T p.L300= | Silent (SNP) | VAF 62/183 reads (34%) | catalogued as COSV63579052; called by muse, mutect2, varscan2
- IFT172 | c.3663G>A p.G1221= | Silent (SNP) | VAF 50/308 reads (16%) | catalogued as rs892273103, COSV53138353; called by muse, mutect2, varscan2
- IGHV4-28 | c.54G>T p.L18= | Silent (SNP) | VAF 27/114 reads (24%) | called by muse, mutect2, varscan2
- KCNT2 | c.474C>T p.S158= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV54105221; called by muse, mutect2
- KIAA1217 | c.4914G>A p.V1638= | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as COSV56814759, COSV56822478; called by muse, mutect2, varscan2
- MRPL47 | c.115T>C p.L39= | Silent (SNP) | VAF 28/388 reads (7%) | catalogued as COSV52021694; called by muse, mutect2
- MTA3 | c.405C>G p.V135= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as COSV101290761, COSV68136439, COSV68136760; called by muse, mutect2
- NCOA2 | c.771C>A p.P257= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV71764812; called by muse, mutect2, varscan2
- OR5AU1 | c.576C>G p.T192= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV58616136; called by muse, mutect2, varscan2
- OR8H3 | c.234C>T p.V78= | Silent (SNP) | VAF 128/1031 reads (12%) | catalogued as COSV57911191; called by muse, mutect2, varscan2
- PCLO | c.11442G>A p.K3814= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as COSV61658940; called by muse, mutect2, varscan2
- PLCH1 | c.2922C>T p.D974= (on ENST00000340059 / NM_001130960.2; = p.D966= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/358 reads (16%) | catalogued as rs1192624001, COSV58208798; called by muse, mutect2, varscan2
- ROBO3 | c.2205T>A p.P735= | Silent (SNP) | VAF 34/148 reads (23%) | catalogued as COSV67302609; called by muse, mutect2, varscan2
- RPS6 | c.186C>T p.P62= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs1429644411, COSV59548761; called by muse, mutect2, varscan2
- SLC35G1 | c.543A>G p.K181= (on ENST00000427197 / NM_001134658.3; = p.K180= on NM_153226.4) | Silent (SNP) | VAF 49/174 reads (28%) | catalogued as COSV65055693; called by muse, mutect2, varscan2
- SPTA1 | c.460T>C p.L154= | Silent (SNP) | VAF 90/325 reads (28%) | catalogued as COSV63758410; called by muse, mutect2, varscan2
- TACC2 | c.6525G>A p.T2175= (on ENST00000334433; = p.T253= on NM_006997.4) | Silent (SNP) | VAF 60/225 reads (27%) | catalogued as rs1371630068, COSV53288646; called by muse, mutect2, varscan2
- TIGIT | c.627G>A p.G209= | Silent (SNP) | VAF 54/342 reads (16%) | catalogued as rs1487153218, COSV67329428; called by muse, mutect2, varscan2
- TMPRSS15 | c.1392T>C p.Y464= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as rs755045381, COSV53039147; called by muse, mutect2, varscan2
- XIRP2 | c.6726T>A p.G2242= (on ENST00000628543; = p.G2417= on NM_152381.6) | Silent (SNP) | VAF 49/174 reads (28%) | catalogued as COSV54730226; called by muse, mutect2, varscan2
